Somatic mutation profile of cancer-model specimen HCM-CSHL-1269-C18-85M (3D Organoid; aliquot HCM-CSHL-1269-C18-85M-01D-A882-36), derived from the metastatic tumor of HCMI case HCM-CSHL-1269-C18, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IVB; Tumor grade: G2; Age at diagnosis: 49.4 years (18,035 days).
Specimen HCM-CSHL-1269-C18-85M: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Organoid; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1b1c8bc7-660b-4a2f-9740-a34828e44328.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-1269-C18-11A (Solid Tissue Normal), aliquot HCM-CSHL-1269-C18-11A-01D-A882-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b3a3a795-a99b-4959-a596-76756969fb1d

The open-access MAF lists 245 somatic variants for this specimen: 190 protein-altering or splice-affecting, 44 silent, 11 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 171, Silent 44, Nonsense Mutation 8, Intron 6, Frame Shift Del 4, Frame Shift Ins 3, 3'UTR 3, Splice Region 3, 5'UTR 1, Splice Site 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.183A>C p.Q61H | Missense Mutation (SNP) | VAF 165/302 reads (55%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.121); catalogued as rs17851045, COSV55498802, COSV55499223, COSV55811221; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.331A>G p.K111E | Missense Mutation (SNP) | VAF 111/301 reads (37%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen probably damaging (0.931); catalogued as rs1057519933, COSV55878486, COSV56029794; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- SMAD4 | c.1140-1G>A p.X380_splice | Splice Site (SNP) | VAF 203/204 reads (100%) | catalogued as rs1555686594, COSV100748399, COSV61690722; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.730G>A p.G244S | Missense Mutation (SNP) | VAF 103/103 reads (100%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057519989, CM144215, COSV52668392, COSV52676997, COSV52808251; ClinVar: pathogenic / likely pathogenic; called by muse, varscan2
- AARS1 | c.2324_2325del p.S775Cfs*22 | Frame Shift Del (DEL) | VAF 58/336 reads (17%) | catalogued as rs1567601355; called by pindel, varscan2
- ABCA8 | c.2546del p.N849Tfs*28 | Frame Shift Del (DEL) | VAF 36/328 reads (11%) | catalogued as rs755807867; called by mutect2, pindel, varscan2
- ACHE | c.1598C>T p.P533L | Missense Mutation (SNP) | VAF 326/677 reads (48%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as rs1362672573; called by muse, varscan2
- ACTL7B | c.974G>A p.R325H | Missense Mutation (SNP) | VAF 54/542 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.005); catalogued as rs756507402, COSV65926820, COSV65928463; called by muse, mutect2, varscan2
- ADAMTS2 | c.1372C>T p.R458C | Missense Mutation (SNP) | VAF 90/318 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); catalogued as rs759185076; called by muse, varscan2
- AMER1 | c.714A>C p.K238N | Missense Mutation (SNP) | VAF 92/753 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.027); catalogued as COSV57664929, COSV57666849; called by muse, mutect2, varscan2
- AMOT | c.1685G>T p.R562L (on ENST00000371959 / NM_001113490.1; = p.R153L on NM_133265.3) | Missense Mutation (SNP) | VAF 85/717 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59061362; called by muse, mutect2, varscan2
- AMY1C | c.952C>T p.R318* | Nonsense Mutation (SNP) | VAF 84/540 reads (16%) | catalogued as rs752371105, COSV64406893; called by muse, mutect2, varscan2
- ANAPC2 | c.1805C>A p.P602Q | Missense Mutation (SNP) | VAF 152/505 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60571567; called by mutect2, varscan2
- ANGPT1 | c.1078G>C p.E360Q | Missense Mutation (SNP) | VAF 57/215 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.931); catalogued as COSV52437907; called by muse, mutect2, varscan2
- ANKRD30A | c.3505A>G p.K1169E (on ENST00000611781; = p.K1113E on NM_052997.2) | Missense Mutation (SNP) | VAF 45/169 reads (27%) | SIFT tolerated (0.21); PolyPhen benign (0.028); catalogued as COSV100654599; called by muse, mutect2, varscan2
- ARID2 | c.4717G>T p.A1573S | Missense Mutation (SNP) | VAF 173/343 reads (50%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); catalogued as COSV57604540; called by muse, mutect2, varscan2
- B4GALNT3 | c.481C>T p.P161S | Missense Mutation (SNP) | VAF 95/262 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56752219; called by muse, mutect2, varscan2
- BRIP1 | c.2149C>G p.L717V | Missense Mutation (SNP) | VAF 15/357 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51993878; called by muse, mutect2
- C2orf16 | c.797dup p.N266Kfs*2 | Frame Shift Ins (INS) | VAF 98/339 reads (29%) | catalogued as rs1167937523; called by mutect2, varscan2
- C3orf33 | c.239G>A p.R80H (on ENST00000340171 / NM_001308229.2; = p.R37H on NM_173657.2) | Missense Mutation (SNP) | VAF 72/369 reads (20%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.982); catalogued as rs752205296; called by muse, mutect2, varscan2
- CCDC172 | c.190T>G p.F64V | Missense Mutation (SNP) | VAF 28/136 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.564); catalogued as COSV60936982; called by muse, mutect2, varscan2
- CDR1 | c.481G>A p.G161R | Missense Mutation (SNP) | VAF 215/700 reads (31%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.549); catalogued as rs761718627, COSV65163988; called by muse, mutect2, varscan2
- CDSN | c.689G>A p.G230E | Missense Mutation (SNP) | VAF 258/956 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs763625404; called by muse, mutect2
- COL11A1 | c.4364C>G p.P1455R | Missense Mutation (SNP) | VAF 82/188 reads (44%) | SIFT tolerated (0.39); PolyPhen probably damaging (0.999); catalogued as COSV100615903; called by muse, mutect2, varscan2
- CORIN | c.2035G>T p.D679Y | Missense Mutation (SNP) | VAF 136/252 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV56686267; called by mutect2, varscan2
- EFL1 | c.664C>A p.H222N | Missense Mutation (SNP) | VAF 26/352 reads (7%) | SIFT tolerated (0.98); PolyPhen benign (0.003); catalogued as rs750177180; called by muse, mutect2
- EYS | c.5472G>A p.M1824I | Missense Mutation (SNP) | VAF 16/532 reads (3%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0); catalogued as rs1320740732; called by muse, mutect2
- FAT3 | c.11311C>T p.R3771C | Missense Mutation (SNP) | VAF 216/358 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs200507277; called by muse, mutect2, varscan2
- FERD3L | c.49G>A p.V17I | Missense Mutation (SNP) | VAF 223/613 reads (36%) | SIFT tolerated (0.07); PolyPhen benign (0.439); catalogued as COSV51761636; called by muse, mutect2, varscan2
- FLG | c.1484C>T p.S495L | Missense Mutation (SNP) | VAF 140/431 reads (32%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.992); catalogued as rs139321371, COSV100910484; called by muse, mutect2, varscan2
- FSTL4 | c.754G>A p.E252K | Missense Mutation (SNP) | VAF 120/390 reads (31%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.489); catalogued as rs138802581; called by muse, varscan2
- GEMIN5 | c.2240C>G p.P747R | Missense Mutation (SNP) | VAF 156/477 reads (33%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.58); catalogued as COSV53562270; called by muse, mutect2, varscan2
- GIMAP1 | c.716G>A p.R239Q | Missense Mutation (SNP) | VAF 210/787 reads (27%) | SIFT tolerated (0.44); PolyPhen benign (0.024); catalogued as rs1381304423, COSV56188765; called by muse, mutect2, varscan2
- GLI3 | c.4021G>A p.G1341S | Missense Mutation (SNP) | VAF 81/690 reads (12%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.003); catalogued as rs775322839, COSV104431688; called by muse, mutect2, varscan2
- GUCY2F | c.1477C>T p.R493C | Missense Mutation (SNP) | VAF 98/319 reads (31%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.762); catalogued as COSV54298014; called by muse, mutect2, varscan2
- HCN2 | c.1519C>T p.R507C | Missense Mutation (SNP) | VAF 67/421 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs368817662; called by muse, mutect2, varscan2
- IQCA1L | c.244G>A p.G82S | Missense Mutation (SNP) | VAF 24/930 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as rs1370173529; called by muse, mutect2
- KCNH5 | c.79A>T p.S27C | Missense Mutation (SNP) | VAF 17/132 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0.314); catalogued as COSV59776894; called by muse, mutect2, varscan2
- KLHL29 | c.1282G>A p.E428K | Missense Mutation (SNP) | VAF 27/293 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.053); catalogued as rs564002560; called by muse, mutect2, varscan2
- KRT33B | c.166G>A p.E56K | Missense Mutation (SNP) | VAF 276/836 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs931017212, COSV52440908; called by muse, mutect2, varscan2
- LAMP1 | c.782A>G p.N261S | Missense Mutation (SNP) | VAF 72/619 reads (12%) | SIFT tolerated (0.12); PolyPhen benign (0.175); catalogued as rs1469959940; called by muse, mutect2, varscan2
- LGI2 | c.821G>A p.G274D | Missense Mutation (SNP) | VAF 23/155 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1234005410; called by muse, mutect2, varscan2
- LY6G6F-LY6G6D | c.686C>T p.T229M | Missense Mutation (SNP) | VAF 455/615 reads (74%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs758526333; called by muse, varscan2
- MAP3K10 | c.2483C>T p.T828M | Missense Mutation (SNP) | VAF 213/388 reads (55%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.452); catalogued as rs1347221571; called by muse, mutect2, varscan2
- MPDZ | c.1897C>T p.R633* | Nonsense Mutation (SNP) | VAF 59/423 reads (14%) | catalogued as rs200955619; called by muse, mutect2, varscan2
- MUC16 | c.8845A>C p.S2949R | Missense Mutation (SNP) | VAF 63/422 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.042); catalogued as rs975223466, COSV101200278; called by muse, mutect2, varscan2
- MYCBP2 | c.12159C>G p.I4053M (on ENST00000357337; = p.I4091M on NM_015057.5) | Missense Mutation (SNP) | VAF 34/578 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV62037391; called by muse, mutect2
- MYLK | c.4325A>T p.E1442V | Missense Mutation (SNP) | VAF 36/490 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.827); catalogued as COSV60622026; called by muse, mutect2
- NOXRED1 | c.728C>T p.A243V | Missense Mutation (SNP) | VAF 144/304 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as rs775895152; called by muse, varscan2
- OOSP2 | c.221G>A p.R74H | Missense Mutation (SNP) | VAF 72/208 reads (35%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as rs752322062, COSV53929152, COSV53930487; called by muse, varscan2
- OR1L6 | c.589G>A p.V197M (on ENST00000373684; = p.V161M on NM_001004453.2) | Missense Mutation (SNP) | VAF 144/554 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs769160847; called by muse, mutect2
- OR2AJ1 | c.710C>A p.S237* | Nonsense Mutation (SNP) | VAF 136/406 reads (33%) | catalogued as rs1478455441; called by muse, mutect2, varscan2
- OR4D5 | c.677G>A p.R226Q | Missense Mutation (SNP) | VAF 165/462 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.199); catalogued as rs142766960, COSV58305795; called by muse, mutect2, varscan2
- OR5J2 | c.431T>G p.L144R | Missense Mutation (SNP) | VAF 59/346 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV56621412; called by muse, mutect2, varscan2
- OTUD6B | c.647G>T p.C216F | Missense Mutation (SNP) | VAF 42/216 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV104374805; called by muse, mutect2, varscan2
- PCF11 | c.510C>T p.P170= | Splice Region (SNP) | VAF 63/232 reads (27%) | catalogued as rs780581736; called by muse, mutect2, varscan2
- PLA2R1 | c.537G>A p.M179I | Missense Mutation (SNP) | VAF 64/374 reads (17%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs1295711146; called by muse, mutect2, varscan2
- PRR14 | c.1322G>A p.G441E | Missense Mutation (SNP) | VAF 94/446 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs755490167; called by muse, mutect2, varscan2
- PSKH2 | c.13G>A p.A5T | Missense Mutation (SNP) | VAF 149/303 reads (49%) | SIFT tolerated, low confidence (0.99); PolyPhen benign (0.003); catalogued as COSV52609254; called by muse, mutect2, varscan2
- PTGER3 | c.809G>C p.S270T | Missense Mutation (SNP) | VAF 15/424 reads (4%) | SIFT tolerated (0.05); PolyPhen benign (0.27); catalogued as rs1441030646; called by muse, mutect2
- RALGAPA2 | c.382G>C p.E128Q | Missense Mutation (SNP) | VAF 26/410 reads (6%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.974); catalogued as COSV99173208; called by muse, mutect2
- RBBP8 | c.1273G>A p.G425S | Missense Mutation (SNP) | VAF 219/219 reads (100%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as rs541964555; called by muse, mutect2, varscan2
- RFX8 | c.1393G>A p.V465M (on ENST00000646446; = p.V394M on NM_001145664.2 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 63/380 reads (17%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.003); catalogued as rs375213952; called by muse, mutect2, varscan2
- RIC8A | c.796G>C p.D266H | Missense Mutation (SNP) | VAF 82/419 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); catalogued as rs765590900; called by muse, mutect2, varscan2
- RNF152 | c.383A>C p.K128T | Missense Mutation (SNP) | VAF 76/330 reads (23%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.981); catalogued as rs757511212; called by muse, mutect2, varscan2
- RRAGC | c.453G>A p.M151I | Missense Mutation (SNP) | VAF 58/110 reads (53%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV100883833, COSV65932008; called by muse, mutect2, varscan2
- SEMA3D | c.416A>C p.N139T | Missense Mutation (SNP) | VAF 13/432 reads (3%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.806); catalogued as COSV52402158; called by muse, mutect2
- SLC15A2 | c.1094G>A p.R365H | Missense Mutation (SNP) | VAF 118/414 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.009); catalogued as rs778014741, COSV55195836, COSV55196344; called by muse, mutect2, varscan2
- SMAD6 | c.1440C>G p.F480L | Missense Mutation (SNP) | VAF 52/263 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.779); catalogued as COSV56594556; called by muse, mutect2, varscan2
- SPOCD1 | c.697C>T p.R233C | Missense Mutation (SNP) | VAF 118/277 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as rs754308003; called by muse, varscan2
- SSX3 | c.544G>A p.D182N | Missense Mutation (SNP) | VAF 158/595 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1454526133, COSV53644128; called by muse, mutect2, varscan2
- SYTL4 | c.1787G>A p.C596Y | Missense Mutation (SNP) | VAF 79/757 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs775999680; called by muse, mutect2, varscan2
- TAF1L | c.5340A>C p.E1780D | Missense Mutation (SNP) | VAF 76/572 reads (13%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.015); catalogued as rs750348291; called by muse, mutect2, varscan2
- TRPV5 | c.2114G>A p.R705H | Missense Mutation (SNP) | VAF 187/826 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs766349018; called by muse, mutect2, varscan2
- WDR19 | c.2483G>A p.R828H | Missense Mutation (SNP) | VAF 159/317 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs771137155, COSV56469396, COSV56470847; called by muse, mutect2, varscan2
- XIRP2 | c.1755A>C p.E585D (on ENST00000628543; = p.E760D on NM_152381.6) | Missense Mutation (SNP) | VAF 79/310 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV54690641; called by muse, mutect2, varscan2
- XKR7 | c.802G>A p.A268T | Missense Mutation (SNP) | VAF 38/526 reads (7%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.597); catalogued as rs1257233237, COSV101629288; called by muse, mutect2
- ZCCHC18 | c.296G>A p.R99H | Missense Mutation (SNP) | VAF 90/638 reads (14%) | SIFT tolerated (0.33); PolyPhen benign (0.003); catalogued as COSV62459241; called by muse, varscan2
- ZNF266 | c.782C>G p.T261S | Missense Mutation (SNP) | VAF 72/445 reads (16%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as COSV63221494; called by muse, mutect2, varscan2
- ZNF804A | c.1417C>G p.L473V | Missense Mutation (SNP) | VAF 27/150 reads (18%) | SIFT tolerated (0.5); PolyPhen benign (0.022); catalogued as COSV56451356; called by muse, mutect2, varscan2
- ZNF862 | c.962C>T p.S321L | Missense Mutation (SNP) | VAF 73/346 reads (21%) | SIFT tolerated, low confidence (0.85); PolyPhen benign (0); catalogued as rs760393168, COSV99783639; called by muse, mutect2, varscan2
- ABCA13 | c.10450G>A p.V3484I | Missense Mutation (SNP) | VAF 99/389 reads (25%) | SIFT tolerated (0.4); PolyPhen benign (0.333); called by muse, mutect2, varscan2
- ACACA | c.1511G>A p.G504E | Missense Mutation (SNP) | VAF 106/327 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ADGRV1 | c.101G>C p.R34T | Missense Mutation (SNP) | VAF 41/276 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.629); called by muse, mutect2, varscan2
- AFTPH | c.1099C>T p.H367Y | Missense Mutation (SNP) | VAF 46/326 reads (14%) | SIFT tolerated (0.12); PolyPhen benign (0.084); called by muse, mutect2, varscan2
- AGMO | c.1198T>G p.F400V | Missense Mutation (SNP) | VAF 36/472 reads (8%) | SIFT tolerated (0.12); PolyPhen benign (0.047); called by muse, mutect2
- AL354761.1 | c.249G>A p.K83= | Splice Region (SNP) | VAF 70/264 reads (27%) | called by muse, varscan2
- AOC1 | c.1577A>C p.K526T | Missense Mutation (SNP) | VAF 37/330 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- AP4E1 | c.1741T>C p.S581P | Missense Mutation (SNP) | VAF 110/224 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- ARG1 | c.41C>G p.P14R | Missense Mutation (SNP) | VAF 32/554 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ARHGAP22 | c.1459C>T p.Q487* | Nonsense Mutation (SNP) | VAF 215/476 reads (45%) | called by muse, mutect2, varscan2
- ARMCX6 | c.83C>G p.T28S | Missense Mutation (SNP) | VAF 101/774 reads (13%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- ASXL3 | c.4549C>A p.P1517T | Missense Mutation (SNP) | VAF 20/380 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- BCKDHB | c.137C>A p.A46D | Missense Mutation (SNP) | VAF 77/615 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- BGN | c.855C>A p.D285E | Missense Mutation (SNP) | VAF 88/609 reads (14%) | SIFT tolerated (0.37); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- BICD2 | c.1303T>A p.L435M | Missense Mutation (SNP) | VAF 80/509 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CACNA1E | c.2360A>C p.K787T | Missense Mutation (SNP) | VAF 97/629 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- CAMTA1 | c.2444C>T p.T815I | Missense Mutation (SNP) | VAF 221/408 reads (54%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- CAP2 | c.1328T>G p.L443R | Missense Mutation (SNP) | VAF 45/331 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- CASK | c.1263G>T p.E421D | Missense Mutation (SNP) | VAF 79/401 reads (20%) | SIFT tolerated (0.53); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CENPJ | c.2450C>T p.S817F | Missense Mutation (SNP) | VAF 77/730 reads (11%) | SIFT tolerated (0.6); PolyPhen benign (0.101); called by muse, mutect2, varscan2
- CFAP54 | c.5098A>C p.K1700Q | Missense Mutation (SNP) | VAF 12/128 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.073); called by muse, mutect2
- CNR1 | c.52_53del p.T18* | Frame Shift Del (DEL) | VAF 55/402 reads (14%) | called by mutect2, pindel, varscan2
- CNTRL | c.6239T>G p.L2080R | Missense Mutation (SNP) | VAF 14/442 reads (3%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.539); called by muse, mutect2
- COL6A6 | c.4742A>C p.K1581T | Missense Mutation (SNP) | VAF 58/321 reads (18%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.661); called by muse, mutect2, varscan2
- CYLC2 | c.879G>C p.K293N | Missense Mutation (SNP) | VAF 87/442 reads (20%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- EPHA4 | c.536A>C p.K179T | Missense Mutation (SNP) | VAF 163/405 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.859); called by muse, mutect2, varscan2
- ERICH1 | c.368T>G p.F123C | Missense Mutation (SNP) | VAF 28/172 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); called by muse, varscan2
- ERICH3 | c.2434T>A p.W812R | Missense Mutation (SNP) | VAF 71/384 reads (18%) | SIFT tolerated (0.65); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- FLNB | c.1587G>A p.W529* | Nonsense Mutation (SNP) | VAF 107/220 reads (49%) | called by muse, mutect2, varscan2
- FN1 | c.4678G>A p.V1560I | Missense Mutation (SNP) | VAF 79/376 reads (21%) | SIFT tolerated (0.54); PolyPhen benign (0.123); called by muse, mutect2, varscan2
- FSIP2 | c.1211C>G p.S404C | Missense Mutation (SNP) | VAF 26/148 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.443); called by muse, mutect2, varscan2
- GALNT12 | c.1007G>A p.G336E | Missense Mutation (SNP) | VAF 72/245 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GRIA2 | c.1204C>A p.L402I | Missense Mutation (SNP) | VAF 80/191 reads (42%) | SIFT tolerated (0.39); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- HASPIN | c.20G>A p.G7E | Missense Mutation (SNP) | VAF 128/128 reads (100%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.058); called by muse, varscan2
- IQSEC3 | c.2272T>C p.F758L (on ENST00000538872 / NM_001170738.2; = p.F455L on NM_015232.1) | Missense Mutation (SNP) | VAF 52/296 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ITGA7 | c.1207T>G p.L403V (on ENST00000555728; = p.L359V on NM_002206.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 101/457 reads (22%) | SIFT tolerated (0.15); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- KDM5B | c.4394C>G p.T1465S | Missense Mutation (SNP) | VAF 34/374 reads (9%) | SIFT tolerated (0.89); PolyPhen benign (0); called by muse, mutect2
- KIAA2013 | c.418G>T p.A140S | Missense Mutation (SNP) | VAF 180/372 reads (48%) | SIFT tolerated (0.83); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- KIT | c.518A>C p.K173T | Missense Mutation (SNP) | VAF 116/457 reads (25%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.82); called by muse, mutect2, varscan2
- LILRA1 | c.648G>T p.E216D | Missense Mutation (SNP) | VAF 125/251 reads (50%) | SIFT deleterious (0.02); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- LPCAT2 | c.1432G>T p.G478W | Missense Mutation (SNP) | VAF 31/305 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.497); called by mutect2, varscan2
- LRP1B | c.3031T>C p.F1011L | Missense Mutation (SNP) | VAF 97/276 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.983); called by muse, varscan2
- MAT2A | c.314_324dup p.A109Tfs*4 | Frame Shift Ins (INS) | VAF 37/206 reads (18%) | called by mutect2, varscan2
- MAT2B | c.266T>G p.V89G | Missense Mutation (SNP) | VAF 34/237 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- MEF2A | c.986C>T p.A329V (on ENST00000557942 / NM_001319206.2; = p.A323V on NM_005587.4 and 8 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 53/256 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- MEGF10 | c.635G>T p.C212F | Missense Mutation (SNP) | VAF 53/310 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NALCN | c.1174A>C p.S392R | Missense Mutation (SNP) | VAF 66/786 reads (8%) | SIFT tolerated (0.35); PolyPhen benign (0.413); called by muse, mutect2
- NDOR1 | c.1651C>G p.Q551E (on ENST00000371521 / NM_001144026.3; = p.Q535E on NM_014434.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/392 reads (3%) | SIFT tolerated (0.46); PolyPhen benign (0.007); called by muse, mutect2
- NHLH2 | c.334A>T p.K112* | Nonsense Mutation (SNP) | VAF 41/337 reads (12%) | called by muse, mutect2, varscan2
- OBI1 | c.560A>T p.K187I | Missense Mutation (SNP) | VAF 50/476 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.03); called by muse, mutect2
- OR10H3 | c.412A>C p.S138R | Missense Mutation (SNP) | VAF 26/537 reads (5%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.616); called by muse, mutect2
- OR1L6 | c.327C>A p.C109* (on ENST00000373684; = p.C73* on NM_001004453.2) | Nonsense Mutation (SNP) | VAF 123/408 reads (30%) | called by muse, mutect2, varscan2
- OR2W1 | c.140T>G p.L47R | Missense Mutation (SNP) | VAF 36/632 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.653); called by muse, mutect2
- OR52B2 | c.604T>G p.F202V | Missense Mutation (SNP) | VAF 44/522 reads (8%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.998); called by muse, mutect2
- PCDHA1 | c.1265A>T p.E422V | Missense Mutation (SNP) | VAF 18/640 reads (3%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.323); called by muse, mutect2
- PCLO | c.15163G>A p.V5055M | Missense Mutation (SNP) | VAF 59/277 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PDE4A | c.1019A>C p.K340T (on ENST00000380702 / NM_001111307.2; = p.K101T on NM_006202.3) | Missense Mutation (SNP) | VAF 57/404 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.675); called by muse, mutect2, varscan2
- PHF12 | c.1757C>T p.T586M | Missense Mutation (SNP) | VAF 413/654 reads (63%) | SIFT deleterious (0.02); PolyPhen benign (0.415); called by muse, mutect2, varscan2
- PIK3CB | c.1067G>C p.G356A | Missense Mutation (SNP) | VAF 26/537 reads (5%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.923); called by muse, mutect2
- PMS2 | c.1810_1825del p.Q604* | Frame Shift Del (DEL) | VAF 52/440 reads (12%) | called by mutect2, pindel
- PNPLA8 | c.1405C>G p.Q469E | Missense Mutation (SNP) | VAF 14/428 reads (3%) | SIFT deleterious (0.01); PolyPhen benign (0.253); called by muse, mutect2
- POU4F2 | c.1001T>C p.L334P | Missense Mutation (SNP) | VAF 119/430 reads (28%) | SIFT tolerated (0.51); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- PPIG | c.578C>G p.S193* | Nonsense Mutation (SNP) | VAF 40/245 reads (16%) | called by muse, mutect2, varscan2
- PSD3 | c.2801A>C p.K934T (on ENST00000440756; = p.K933T on NM_015310.4) | Missense Mutation (SNP) | VAF 40/84 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.131); called by muse, varscan2
- PTPN3 | c.1981G>C p.A661P | Missense Mutation (SNP) | VAF 41/382 reads (11%) | SIFT deleterious (0.05); PolyPhen benign (0); called by muse, mutect2, varscan2
- RAB11FIP1 | c.1604C>A p.T535N | Missense Mutation (SNP) | VAF 109/215 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RIMS1 | c.4559T>C p.L1520P | Missense Mutation (SNP) | VAF 76/428 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- RWDD1 | c.223C>G p.L75V | Missense Mutation (SNP) | VAF 22/332 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.82); called by muse, mutect2
- SAMD9 | c.1178A>C p.K393T | Missense Mutation (SNP) | VAF 46/480 reads (10%) | SIFT tolerated (0.05); PolyPhen benign (0.077); called by muse, mutect2
- SHPRH | c.3659G>C p.R1220P (on ENST00000275233 / NM_001042683.3; = p.R1224P on NM_173082.3) | Missense Mutation (SNP) | VAF 56/425 reads (13%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.693); called by muse, mutect2, varscan2
- SLC16A14 | c.68A>C p.K23T | Missense Mutation (SNP) | VAF 59/359 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- SLC2A13 | c.772T>A p.F258I | Missense Mutation (SNP) | VAF 38/292 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.566); called by muse, mutect2, varscan2
- SLC2A14 | c.354G>A p.M118I | Missense Mutation (SNP) | VAF 96/237 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.348); called by muse, mutect2, varscan2
- SNX9 | c.1117G>A p.E373K | Missense Mutation (SNP) | VAF 73/428 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SP8 | c.173G>T p.G58V (on ENST00000361443 / NM_198956.4; = p.G76V on NM_182700.6) | Missense Mutation (SNP) | VAF 24/318 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); called by muse, mutect2
- SYCP2 | c.2548dup p.S850Kfs*11 | Frame Shift Ins (INS) | VAF 62/360 reads (17%) | called by mutect2, varscan2
- SYNE1 | c.8664T>A p.D2888E (on ENST00000367255 / NM_182961.4; = p.D2895E on NM_033071.3) | Missense Mutation (SNP) | VAF 41/282 reads (15%) | SIFT tolerated (0.38); PolyPhen benign (0.101); called by muse, mutect2, varscan2
- SYNE2 | c.14987A>T p.K4996I | Missense Mutation (SNP) | VAF 28/138 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- SYNGAP1 | c.3875T>A p.L1292H | Missense Mutation (SNP) | VAF 101/597 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.82); called by muse, mutect2, varscan2
- TDRD15 | c.2310C>G p.D770E | Missense Mutation (SNP) | VAF 37/308 reads (12%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.955); called by muse, mutect2, varscan2
- TEX14 | c.3087C>T p.T1029= (on ENST00000240361 / NM_001201457.2; = p.T1023= on NM_031272.5) | Splice Region (SNP) | VAF 89/219 reads (41%) | called by muse, mutect2, varscan2
- THADA | c.5180T>G p.L1727R | Missense Mutation (SNP) | VAF 49/310 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- THOC5 | c.416A>T p.H139L | Missense Mutation (SNP) | VAF 44/206 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TLR4 | c.1655G>A p.S552N (on ENST00000355622 / NM_138554.5; = p.S512N on NM_003266.4) | Missense Mutation (SNP) | VAF 114/355 reads (32%) | SIFT tolerated (0.07); PolyPhen benign (0.392); called by muse, mutect2, varscan2
- TMEM119 | c.757C>G p.L253V | Missense Mutation (SNP) | VAF 67/441 reads (15%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- TMEM26 | c.164A>C p.K55T | Missense Mutation (SNP) | VAF 51/238 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TNFRSF19 | c.359G>T p.G120V | Missense Mutation (SNP) | VAF 72/419 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TNFRSF8 | c.1073C>A p.S358Y | Missense Mutation (SNP) | VAF 148/282 reads (52%) | SIFT deleterious (0); PolyPhen benign (0.254); called by muse, mutect2, varscan2
- TRIP12 | c.2495A>C p.K832T | Missense Mutation (SNP) | VAF 30/260 reads (12%) | SIFT tolerated (0.41); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- TTC29 | c.1070G>C p.S357T | Missense Mutation (SNP) | VAF 60/215 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.288); called by muse, mutect2, varscan2
- TTN | c.102328A>C p.S34110R (on ENST00000591111; = p.S26686R on NM_003319.4) | Missense Mutation (SNP) | VAF 54/257 reads (21%) | PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TXNL4B | c.107C>A p.P36H | Missense Mutation (SNP) | VAF 70/349 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- UBA6 | c.845A>G p.Y282C | Missense Mutation (SNP) | VAF 91/205 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- USP2 | c.764G>T p.R255I | Missense Mutation (SNP) | VAF 113/345 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.134); called by muse, mutect2, varscan2
- USP53 | c.2245T>G p.L749V | Missense Mutation (SNP) | VAF 110/204 reads (54%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- VCAN | c.2143A>G p.K715E | Missense Mutation (SNP) | VAF 39/320 reads (12%) | SIFT tolerated (0.43); PolyPhen benign (0.104); called by muse, mutect2, varscan2
- VCAN | c.2144A>T p.K715I | Missense Mutation (SNP) | VAF 40/325 reads (12%) | SIFT tolerated (0.19); PolyPhen benign (0.23); called by muse, mutect2, varscan2
- VEPH1 | c.2466A>C p.K822N | Missense Mutation (SNP) | VAF 55/434 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.276); called by muse, mutect2, varscan2
- XKR3 | c.660G>T p.Q220H | Missense Mutation (SNP) | VAF 122/241 reads (51%) | SIFT tolerated (0.11); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- XRN1 | c.3647C>A p.P1216H | Missense Mutation (SNP) | VAF 31/294 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.628); called by muse, mutect2, varscan2
- XYLT2 | c.1750G>A p.E584K | Missense Mutation (SNP) | VAF 48/304 reads (16%) | SIFT tolerated (0.31); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- YME1L1 | c.1950A>T p.Q650H (on ENST00000326799 / NM_139312.3; = p.Q593H on NM_014263.4) | Missense Mutation (SNP) | VAF 55/238 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- ZIM3 | c.550A>C p.S184R | Missense Mutation (SNP) | VAF 45/312 reads (14%) | SIFT tolerated (0.72); PolyPhen probably damaging (0.925); called by muse, mutect2, varscan2
- ZNF182 | c.891A>C p.K297N | Missense Mutation (SNP) | VAF 103/783 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- ZNF3 | c.581C>T p.P194L | Missense Mutation (SNP) | VAF 184/722 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.013); called by muse, varscan2
- ZNF462 | c.6761T>G p.L2254R | Missense Mutation (SNP) | VAF 22/525 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- ZNF567 | c.931T>A p.C311S (on ENST00000536254 / NM_001322913.1; = p.C280S on NM_152603.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 126/241 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZNF658 | c.854T>G p.V285G | Missense Mutation (SNP) | VAF 30/251 reads (12%) | SIFT tolerated (0.14); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- ZNF691 | c.70C>A p.P24T | Missense Mutation (SNP) | VAF 14/278 reads (5%) | SIFT tolerated (0.37); PolyPhen benign (0); called by muse, mutect2
- AHSP | c.150C>T p.N50= | Silent (SNP) | VAF 156/364 reads (43%) | called by muse, mutect2, varscan2
- AMACR | c.864C>T p.D288= | Silent (SNP) | VAF 79/601 reads (13%) | catalogued as rs752187529, COSV56873444; called by muse, mutect2, varscan2
- ARHGAP17 | c.2410A>C p.R804= (on ENST00000289968 / NM_001006634.3; = p.R726= on NM_018054.6) | Silent (SNP) | VAF 28/611 reads (5%) | called by muse, mutect2
- CARD6 | c.1008A>G p.R336= | Silent (SNP) | VAF 78/474 reads (16%) | called by muse, mutect2, varscan2
- CD46 | c.12C>G p.P4= | Silent (SNP) | VAF 114/421 reads (27%) | called by muse, mutect2, varscan2
- CFAP65 | c.1917C>T p.D639= | Silent (SNP) | VAF 67/450 reads (15%) | catalogued as rs145735301; called by muse, mutect2, varscan2
- CHML | c.1143C>T p.G381= | Silent (SNP) | VAF 126/367 reads (34%) | called by muse, mutect2, varscan2
- CORO7 | c.2403G>T p.L801= | Silent (SNP) | VAF 80/606 reads (13%) | called by muse, mutect2, varscan2
- EFL1 | c.663T>A p.S221= | Silent (SNP) | VAF 26/349 reads (7%) | called by muse, mutect2
- ELL | c.423G>C p.T141= | Silent (SNP) | VAF 173/627 reads (28%) | called by muse, mutect2, varscan2
- FAM160A1 | c.3117C>T p.C1039= | Silent (SNP) | VAF 38/209 reads (18%) | called by muse, mutect2, varscan2
- FNDC7 | c.1707T>G p.A569= | Silent (SNP) | VAF 74/277 reads (27%) | called by muse, mutect2, varscan2
- FRY | c.1203A>C p.R401= | Silent (SNP) | VAF 35/483 reads (7%) | called by muse, mutect2
- HAO2 | c.529T>C p.L177= | Silent (SNP) | VAF 22/260 reads (8%) | called by muse, mutect2
- HNRNPH2 | c.306G>A p.P102= | Silent (SNP) | VAF 213/886 reads (24%) | catalogued as rs56052724, COSV99516185; called by muse, mutect2, varscan2
- HYDIN | c.11322G>A p.T3774= | Silent (SNP) | VAF 59/185 reads (32%) | catalogued as rs529795965; called by muse, mutect2, varscan2
- INVS | c.2226G>A p.V742= | Silent (SNP) | VAF 89/437 reads (20%) | called by muse, mutect2, varscan2
- KRT74 | c.858C>A p.I286= | Silent (SNP) | VAF 52/217 reads (24%) | catalogued as rs1233826515; called by muse, mutect2, varscan2
- MCF2 | c.345T>C p.F115= | Silent (SNP) | VAF 164/517 reads (32%) | called by muse, mutect2, varscan2
- MGAM | c.1131G>A p.A377= | Silent (SNP) | VAF 169/380 reads (44%) | catalogued as rs1554461448, COSV101527453; called by muse, mutect2, varscan2
- MIDEAS | c.1062C>T p.I354= | Silent (SNP) | VAF 40/379 reads (11%) | called by muse, mutect2, varscan2
- MYMK | c.363C>T p.P121= | Silent (SNP) | VAF 20/556 reads (4%) | called by muse, mutect2
- MYOC | c.1020G>A p.E340= | Silent (SNP) | VAF 145/502 reads (29%) | catalogued as rs534806873; called by muse, mutect2, varscan2
- NEK9 | c.750G>A p.T250= | Silent (SNP) | VAF 87/175 reads (50%) | catalogued as rs1040448591, COSV99464532; called by muse, mutect2, varscan2
- NRXN1 | c.1950T>C p.D650= | Silent (SNP) | VAF 32/432 reads (7%) | catalogued as rs1371366756, COSV58484722; called by muse, mutect2
- PCDHGA5 | c.1458A>C p.R486= | Silent (SNP) | VAF 76/483 reads (16%) | called by muse, mutect2, varscan2
- PLEC | c.11958G>A p.P3986= (on ENST00000322810 / NM_201380.4; = p.P3876= on NM_000445.5) | Silent (SNP) | VAF 103/195 reads (53%) | catalogued as rs546817334; ClinVar: likely benign; called by muse, mutect2, varscan2
- PLTP | c.726T>G p.T242= | Silent (SNP) | VAF 26/805 reads (3%) | called by muse, mutect2
- POLR3F | c.663C>T p.C221= | Silent (SNP) | VAF 180/496 reads (36%) | catalogued as rs759357302, COSV101112295; called by muse, mutect2, varscan2
- PRAG1 | c.4167G>A p.A1389= | Silent (SNP) | VAF 245/245 reads (100%) | called by muse, mutect2, varscan2
- PTCHD1 | c.234C>T p.R78= | Silent (SNP) | VAF 204/972 reads (21%) | called by muse, mutect2, varscan2
- RAP1GAP | c.1167G>A p.T389= | Silent (SNP) | VAF 77/298 reads (26%) | catalogued as rs920149481, COSV51573770; called by muse, mutect2, varscan2
- RPUSD4 | c.618G>A p.E206= | Silent (SNP) | VAF 32/435 reads (7%) | called by muse, mutect2
- SH2D3C | c.93T>C p.T31= | Silent (SNP) | VAF 54/328 reads (16%) | catalogued as rs1160311605; called by muse, mutect2, varscan2
- SLC16A12 | c.867C>G p.S289= | Silent (SNP) | VAF 152/338 reads (45%) | catalogued as COSV57950652; called by muse, mutect2, varscan2
- SRC | c.183C>T p.P61= | Silent (SNP) | VAF 476/1162 reads (41%) | called by muse, varscan2
- TAGLN2 | c.186A>G p.L62= | Silent (SNP) | VAF 79/244 reads (32%) | catalogued as rs1377762534, COSV100230954; called by muse, mutect2, varscan2
- TRPS1 | c.3336G>T p.R1112= (on ENST00000220888 / NM_001330599.2; = p.R1125= on NM_014112.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 76/315 reads (24%) | called by muse, mutect2, varscan2
- UBE2A | c.12G>A p.P4= | Silent (SNP) | VAF 232/570 reads (41%) | called by muse, varscan2
- UBE3A | c.1861C>T p.L621= | Silent (SNP) | VAF 87/198 reads (44%) | called by muse, mutect2, varscan2
- UBXN7 | c.744T>G p.S248= | Silent (SNP) | VAF 27/522 reads (5%) | called by muse, mutect2
- USF1 | c.753C>T p.I251= | Silent (SNP) | VAF 16/440 reads (4%) | catalogued as COSV57036135; called by muse, mutect2
- ZIC3 | c.633G>A p.A211= | Silent (SNP) | VAF 130/875 reads (15%) | called by muse, mutect2, varscan2
- ZNF439 | c.1209T>G p.T403= | Silent (SNP) | VAF 74/503 reads (15%) | called by muse, mutect2, varscan2
- CCDC39 | c.2266-565C>A | Intron (SNP) | VAF 110/334 reads (33%) | called by mutect2, varscan2
- DNAH14 | c.2938+1969T>C | Intron (SNP) | VAF 35/277 reads (13%) | called by muse, mutect2, varscan2
- ESRRG | c.56+15852A>C | Intron (SNP) | VAF 52/284 reads (18%) | catalogued as COSV63151254, COSV63163823; called by muse, mutect2, varscan2
- MAMLD1 | c.*1743G>C | 3'UTR (SNP) | VAF 17/489 reads (3%) | catalogued as rs1183162622; called by muse, mutect2
- MIAT | n.1001C>T | RNA (SNP) | VAF 28/218 reads (13%) | called by muse, mutect2, varscan2
- PEG10 | c.*1037C>T | 3'UTR (SNP) | VAF 51/467 reads (11%) | called by muse, mutect2, varscan2
- SUCO | c.-90C>T | 5'UTR (SNP) | VAF 180/582 reads (31%) | catalogued as rs1280934071; called by muse, varscan2
- TTN | c.10360+3975C>T | Intron (SNP) | VAF 64/172 reads (37%) | called by muse, varscan2
- TXNDC8 | c.255+2305A>C | Intron (SNP) | VAF 18/163 reads (11%) | called by muse, mutect2, varscan2
- UNC13B | c.762-6099A>C | Intron (SNP) | VAF 46/297 reads (15%) | called by muse, mutect2, varscan2
- XIRP2 | c.*1199A>G | 3'UTR (SNP) | VAF 16/270 reads (6%) | catalogued as rs781776454; called by muse, mutect2
